Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4768, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4768-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

with incidental left renal mass.

Specimens Submitted:

- 1: SP: Kidney, left, partial nephrectomy:
- 2: SP: Lymph nodes, para-aortic, excision:
- 3: SP: Cyst wall, excision:
- 4: SP: Cyst wall #2, excision:

DIAGNOSIS:

1. SP: Kidney, left, partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 3.0 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

N/A

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

N/A

Lymph Nodes:

N/A

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

-
2. SP: Lymph nodes, para-aortic, excision:

Lymph Nodes:

Not Involved

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Number of nodes examined:7
Number of metastatic nodes:0

3. SP: Cyst wall, excision: [REDACTED]
Benign cortical cyst.

4. SP: Cyst wall #2, excision: [REDACTED]
Benign cortical cyst.

Gross Description:

1) The specimen is received fresh for frozen section diagnosis, labeled, "Left renal tumor (stitch marks deep margin)". It consists of a resected kidney with attached perinephric fat, measuring overall 6.8 x 3.7 x 3.2 cm and weighing 33 gm. The surgical margin is inked black. Serial sections through the kidney reveal a well-circumscribed, bright yellow, focally hemorrhagic tumor mass measuring 3.0 x 2.6 x 2.2 cm. The mass is located 0.2 cm from the inked surgical margin. A small portion of bright yellow tumor mass is seen to be infiltrating the fat on the opposite end of the surgical margin, measuring 0.6 x 0.4 cm. Representative sections are submitted. A portion of tumor is submitted for [REDACTED]

Summary of Sections:

FSC – frozen section control

TWM – tumor with margins

TWF – tumor within fat

T – tumor

NK – normal kidney, representative sections

2) The specimen is received in formalin, labeled, "Para-aortic lymph nodes". It consists of an irregular piece of tan-yellow fatty tissue admixed with blood, measuring 3.7 x 2.4 x 0.6 cm. Several tan-pink lymph nodes, measuring from 0.4 up to 0.8 cm in greatest dimension are dissected. The larger lymph nodes are bisected and the entire lymph nodes are submitted.

Summary of Sections:

LN1BS – lymph node one bisected

LN2BS – lymph node two bisected

LN - lymph nodes

3) The specimen is received in formalin, labeled, "Cyst wall". It consists of an irregular piece of tan-pink soft tissue with attached fat measuring overall 1.5 x 1.4 x 0.6 cm. The cyst wall appears hemorrhagic and the wall measures 1.6 x 0.5 cm. The specimen is serially sectioned and entirely submitted.

Summary of Sections:

UD – undesignated

4) The specimen is received in formalin, labeled, "Cyst wall #2". It consists of two irregular pieces of tan-pink soft tissue measuring 1.4 and 1.7 cm in greatest dimension. The entire specimen is submitted.

Summary of Sections:

UD - undesignated

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Summary of Sections:

Part 1: SP: Kidney, left, partial nephrectomy: [REDACTED]

Block	Sect. Site	PCs
1	fsc	1
1	nk	1
1	t	1
1	twf	1
2	twm	2

Part 2: SP: Lymph nodes, para-aortic, excision: [REDACTED]

Block	Sect. Site	PCs
2	ln	4
1	ln1bs	2
1	ln2bs	2

Part 3: SP: Cyst wall, excision: [REDACTED]

Block	Sect. Site	PCs
2	ud	2

Part 4: SP: Cyst wall #2, excision: [REDACTED]

Block	Sect. Site	PCs
1	ud	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: MARGIN FREE OF TUMOR. RENAL CORTICAL NEOPLASM, FAVOR RENAL CELL CARCINOMA. [REDACTED]
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 14b12cc8-d512-40e1-bca1-6bd83d4e24a5 (TCGA-BP-4768.8B350A11-7088-42FE-B76E-04FD9470322C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).